Somatic mutation profile of tumor specimen BA2443D (aliquot aq-BA2443D) from BEATAML1.0 case 2187, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.5 years (18,438 days).
Specimen BA2443D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd231a1c-ef18-4aee-a1d7-2c15201d896f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2548D (Solid Tissue Normal), aliquot aq-BA2548D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3297fc9b-dd15-4238-943d-2f37b2dacb45

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRSF2 | c.284C>G p.P95R | Missense Mutation (SNP) | VAF 14/63 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, mutect2, varscan2
- SMYD5 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as rs753802725; called by muse, mutect2, varscan2
- TNRC18 | c.3695C>T p.S1232F | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as rs747760066, COSV68166541; called by muse, mutect2, varscan2
- COBL | c.3052G>T p.G1018C | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.628); called by muse, mutect2
- ELF2 | c.1198T>A p.S400T (on ENST00000379550 / NM_001331036.2; = p.S340T on NM_006874.4) | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- TMED5 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
